Somatic mutation profile of tumor specimen 0DHX3L from CCDI case PBBTPZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 21.2 years (7,743 days).
Specimen 0DHX3L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a587cae1-3680-4d27-832d-0ead5e7f549d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHX1Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0e9dbaf-c467-434a-bda4-e3b3645c8cbd

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 4, Silent 2, 5'UTR 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 168/639 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 97/410 reads (24%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 166/745 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GGCX | c.1167C>G p.N389K | Missense Mutation (SNP) | VAF 177/664 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs768656689; called by muse, mutect2, varscan2
- RIPK3 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs748449238, COSV53477835; called by muse, mutect2, varscan2
- SHPRH | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 135/562 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762906340; called by muse, mutect2, varscan2
- SUPT20HL2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 69/416 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774387646; called by muse, mutect2, varscan2
- SVIL | c.3305C>T p.A1102V (on ENST00000355867 / NM_021738.3; = p.A676V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/692 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.359); catalogued as rs1355144896; called by muse, mutect2
- ZBTB24 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 114/395 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs773712148, COSV57784359; called by muse, mutect2, varscan2
- AC004922.1 | c.49A>G p.N17D | Missense Mutation (SNP) | VAF 141/641 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- BLOC1S5 | c.109A>G p.K37E | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- GPRASP2 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 118/485 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMP20 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 233/815 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, varscan2
- TFEC | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 177/794 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZXDB | c.1762C>G p.L588V | Missense Mutation (SNP) | VAF 168/677 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NLRP5 | c.1890G>A p.S630= | Silent (SNP) | VAF 131/474 reads (28%) | catalogued as rs758788771, COSV66762147; called by muse, mutect2, varscan2
- RAPGEF1 | c.2748C>T p.I916= | Silent (SNP) | VAF 138/452 reads (31%) | catalogued as rs1564448204; called by muse, mutect2, varscan2
- ACCS | c.*88C>G | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- ASB5 | c.-68C>T | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- GART | c.598-47_598-46del | Intron (DEL) | VAF 26/95 reads (27%) | called by mutect2, varscan2
- MAPKBP1 | c.207-70T>A | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- TRIML2 | c.621+768G>A | Intron (SNP) | VAF 158/612 reads (26%) | called by muse, mutect2, varscan2
